Somatic mutation profile of tumor specimen TCGA-HT-8018-01A (aliquot TCGA-HT-8018-01A-11D-2395-08) from TCGA case TCGA-HT-8018, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 40.8 years (14,910 days).
Specimen TCGA-HT-8018-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6e15a3c-d903-4199-9193-7e2ad96588c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-8018-10A (Blood Derived Normal), aliquot TCGA-HT-8018-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14b57d57-bdf2-489e-b4f2-8c971d48475b

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 2, Nonsense Mutation 2, Silent 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 17/106 reads (16%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATRX | c.3785A>G p.D1262G | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV64879193; called by muse, mutect2
- BPIFC | c.719C>G p.T240S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as COSV55913580, COSV55913716; called by muse, mutect2, varscan2
- GGT5 | c.1108G>T p.D370Y | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs779678448, COSV54068850; called by muse, mutect2, varscan2
- IFRD1 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs926241278, COSV50044545; called by muse, mutect2, varscan2
- MYT1 | c.1219C>T p.Q407* | Nonsense Mutation (SNP) | VAF 19/71 reads (27%) | catalogued as COSV60508800; called by muse, mutect2, varscan2
- NPHS1 | c.2399G>A p.R800H | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.616); catalogued as rs146400394; called by muse, mutect2, varscan2
- PDZD4 | c.1906G>A p.V636M | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51248243; called by muse, mutect2
- QRICH1 | c.1930A>G p.K644E | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV58708275; called by muse, mutect2, varscan2
- RGS12 | c.1445G>A p.G482E | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as COSV60907116; called by muse, mutect2, varscan2
- SHKBP1 | c.1468G>A p.G490S | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0.119); catalogued as rs753955774, COSV52538073; called by mutect2, varscan2
- TMEM63B | c.1624C>T p.R542C | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779104826, COSV52477120; called by muse, mutect2, varscan2
- VSIG4 | c.289T>C p.S97P | Missense Mutation (SNP) | VAF 10/227 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66074194; called by muse, mutect2
- VPS16 | c.200_202del p.D67_I68delinsV | In Frame Del (DEL) | VAF 19/104 reads (18%) | called by mutect2, pindel, varscan2
- RBMS3 | c.21G>A p.Q7= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as COSV56153846; called by muse, mutect2, varscan2
- CYP11B1 | c.239+189C>A | Intron (SNP) | VAF 9/48 reads (19%) | catalogued as COSV52828576; called by muse, mutect2, varscan2
- PCDH11X | c.3033+23C>A | Intron (SNP) | VAF 6/136 reads (4%) | catalogued as rs1295121685, COSV100008203; called by muse, mutect2
